Somatic mutation profile of tumor specimen 0DEYDW from CCDI case PBBRIH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.6 years (2,418 days).
Specimen 0DEYDW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46ea3a8f-7c0e-4054-881d-1716d8ba84b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEYDN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75336005-85ef-4236-a96b-cd11f0b124c3

The open-access MAF lists 24 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 7, RNA 2, Nonsense Mutation 1, Frame Shift Ins 1, Splice Site 1, 5'UTR 1, Silent 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLRN1 | c.502dup p.I168Nfs*5 (on ENST00000327047 / NM_174878.3; = p.I92Nfs*5 on NM_052995.2) | Frame Shift Ins (INS) | VAF 113/464 reads (24%) | catalogued as rs746523071; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AFAP1L2 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 93/273 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs749119012; called by muse, mutect2, varscan2
- DNAH6 | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 129/563 reads (23%) | catalogued as COSV52882878; called by muse, mutect2, varscan2
- OTOGL | c.4274G>A p.R1425Q (on ENST00000547103; = p.R1416Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 103/475 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs374659070; called by muse, mutect2, varscan2
- BTBD11 | c.2052G>C p.E684D (on ENST00000280758 / NM_001018072.2; = p.E221D on NM_001017523.2) | Missense Mutation (SNP) | VAF 84/409 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 46/1260 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 32/816 reads (4%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- CLSTN3 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HTRA4 | c.771+1G>C p.X257_splice | Splice Site (SNP) | VAF 12/270 reads (4%) | called by muse, mutect2
- LIPN | c.346A>G p.M116V | Missense Mutation (SNP) | VAF 64/329 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- PHGDH | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 34/309 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIRREL3 | c.231C>T p.F77= | Silent (SNP) | VAF 87/331 reads (26%) | catalogued as rs768135124, COSV73104526; called by muse, mutect2, varscan2
- ATP2B1 | c.788-100T>A | Intron (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- EYS | c.1767-7897G>A | Intron (SNP) | VAF 103/583 reads (18%) | catalogued as rs762942306; called by muse, mutect2, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 7/81 reads (9%) | called by muse, varscan2
- LILRA2 | c.1255+1386C>A | Intron (SNP) | VAF 68/469 reads (14%) | called by muse, mutect2, varscan2
- LINC02694 | n.552G>A | RNA (SNP) | VAF 18/160 reads (11%) | catalogued as rs768118261; called by muse, varscan2
- MBD3L2 | c.*26T>A | 3'UTR (SNP) | VAF 7/34 reads (21%) | catalogued as rs750057068; called by muse, mutect2, varscan2
- MUC19 | n.5228G>A | RNA (SNP) | VAF 60/456 reads (13%) | called by muse, varscan2
- NDUFA7 | chr19:8308386 T>C | 3'Flank (SNP) | VAF 10/107 reads (9%) | catalogued as rs1378300829; called by mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 24/158 reads (15%) | called by muse, varscan2
- SVIL | c.4634-77G>A | Intron (SNP) | VAF 8/72 reads (11%) | called by muse, varscan2
- SYTL2 | c.1562-58T>A | Intron (SNP) | VAF 26/244 reads (11%) | called by muse, mutect2, varscan2
- TIA1 | c.583+160T>G | Intron (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2, varscan2
